Surgical pathology report (de-identified scan), TCGA case TCGA-G3-A3CJ, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Alberta Health Services, specimen TCGA-G3-A3CJ-01A (Primary Tumor).

[page 1 of 4]
1CD-0-3

carcinoma, hepatocellular, NOS 8170/3

Site: liver c22.0

bw
10/15/11

MRN:

PHN:

ACB:

DOB/Gender:

Telephone:

Encounter:

Location:

Ordering:

Surgical Pathology Report

Inquiry Numbers:

Accession Number:

Collected Date:

Pathologist:

Received Date/Time:

Specimen Description

- A. Gallbladder
- B. Right lobe of liver

Clinical Information

Hep C and new hepatocellular cancer right liver; previous Interferon and Ribavirin several years ago; pre-op portal vein embolization.

OK

INFECTIOUS PATIENT: YES - Hep C.

Diagnosis

A. Gallbladder:

Within Normal Limits

1 Normal Cystic Duct Lymph node also Identified (0/1)

B. Right lobe of liver:

1) Hepatocellular Carcinoma, Grade 2/4 (Size 12.0 cm)
With Lymphovascular Invasion

Primary tumor 1.0 cm away from inked resection margin
Portal Vein Metastases come to within 0.4 cm of the inked margin

Post embolization changes noted within portal vein including
foreign body type giant cell reaction and thrombus formation

Cc:

Chart Request ID:

Print Date/Time:

Size Is (circle):		DISQUALIFIED

Pathology: Provider - Permanent
Page 1 of 4

[page 2 of 4]
MRN:
PHN:
ACB:

Inquiry Numbers

Surgical Pathology Report

Accession Number:

Collected Date:

Pathologist:

Received Date/Time:

2)Chronic Hepatitis C infection, Mildly Active

Reported by:

Electronically signed by:

Verified:

Synoptic Report

B: Liver, Resection, Macroscopic

Specimen:

Liver

Gallbladder

PROCEDURE:

Partial hepatectomy

*Major hepatectomy (3 segments or more)

TUMOR SIZE:

Greatest dimension: 12 cm

TUMOR FOCALITY:

Solitary (specify location): Right Lobe

B: Liver, Resection, Microscopic

HISTOLOGIC TYPE:

Hepatocellular carcinoma

HISTOLOGIC GRADE:

GII: Moderately differentiated

TUMOR EXTENSION (select all that apply):

Tumor confined to liver

PRIMARY TUMOR (pT):

pT2: Solitary tumor with vascular invasion or multiple tumors none more than 5 cm

REGIONAL LYMPH NODES (pN):

pNX: Cannot be assessed

DISTANT METASTASIS (pM):

Cc:

Chart Request ID:

Print Date/Time:

Pathology: Provider - Permanent
Page 2 of 4

[page 3 of 4]
MRN:
PHN:
ACB:

Inquiry Numbers:

Surgical Pathology Report**Accession Number:****Collected Date:****Pathologist:****Received Date/Time:**

pMX: Cannot be assessed

MARGINS:

Parenchymal margin uninvolved by invasive carcinoma

Distance of invasive carcinoma from closest margin: 10 mm

***VENOUS (LARGE VESSEL) INVASION (V):**

*Present

***ADDITIONAL PATHOLOGIC FINDINGS:**

*Hepatitis (specify type): Hepatitis C

Gross Description

Received are specimens A to B. All requisitions and specimen containers are labelled with the patient's name
The cassettes and AP identifiers are labelled with the Surgical Number

Gross photos are taken of the specimen.

A. Devitalization - Fixation Times

Devitalization Time: 1054

Fixation Start Time: Not specified on requisition.

Total Fixation Time: Not specified on requisition.

The specimen consists of an intact formalin-fixed gallbladder measuring 7.5 x 4.0 x 2.5 cm. A cystic duct lymph node is identified. No gallstones are noted in the gallbladder and mucosal wall appears normal in thickness. No masses or nodules are seen in the gallbladder either. Representative sections are submitted in a single cassette.

B. Devitalization - Fixation Times

Devitalization Time: 1131

Fixation Start Time: Not specified on requisition.

Total Fixation Time: Not specified on requisition.

The specimen consists of a right lobe of liver weighing 1254 g. Within the liver, there is a circumscribed tumor mass measuring 12.0 cm in maximum dimension. The nodule has areas of hemorrhage and necrosis. Smaller nodules are noted in the surrounding hepatic parenchyma measuring between 0.1 cm to 4.0 mm. Also, the hepatic vein seems to have a clot in it, the largest clot measuring up to 0.5 cm in diameter. The surrounding liver appears congested but is not definitely cirrhotic. The multiple smaller nodules are tumor noted may be grossly consistent with vascular invasion. The

Cc:

Chart Request ID:**Print Date/Time:**

Pathology: Provider - Permanent
Page 3 of 4

[page 4 of 4]
MRN:
PHN:
ACB:

Inquiry Number

Surgical Pathology Report

Accession Number:

Collected Date:

Pathologist:

Received Date/Time:

main tumor mass comes to within 1.0 cm of the inked resection margin, though the smaller possible intravascular ones come closer to within 0.4 cm. The tumor has a greenish appearance to it.

Representative sections are taken as follows:

- B1 - section of liver and nearest resection margin to the tumor.
- B2 - representative sections of uninvolved liver.
- B3 - sections of intravascular blood clot.
- B4 through B9 - sections of tumor.

Cc:

Chart Request ID:

Print Date/Time:

Pathology: Provider - Permanent
Page 4 of 4

Source: NCI Genomic Data Commons file 807411e1-6133-46cd-8156-7ed3a65b1a8c (TCGA-G3-A3CJ.191868C4-3299-4E65-9DB2-C8C43CB83963.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).